Somatic mutation profile of tumor specimen MP2PRT-PAUUWK-TMP1-A (aliquot MP2PRT-PAUUWK-TMP1-A-1-0-D-A83C-36) from MP2PRT case MP2PRT-PAUUWK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,365 days).
Specimen MP2PRT-PAUUWK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d57a8dc-32dc-4579-9e96-c242d7c5736b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUUWK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUUWK-NB1-A-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4ea30c9-fcbe-4c52-ac4f-fb921a5043d1

The open-access MAF lists 286 somatic variants for this specimen: 191 protein-altering or splice-affecting, 77 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 169, Silent 77, Nonsense Mutation 15, Intron 11, Splice Site 3, RNA 3, 5'Flank 2, Frame Shift Del 2, 3'UTR 1, Nonstop Mutation 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAV3 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.225); catalogued as rs199476325, CM080127; ClinVar: not provided / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CC2D2A | c.2671G>A p.E891K | Missense Mutation (SNP) | VAF 62/372 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs863225178; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 29/286 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.1307G>C p.G436A | Missense Mutation (SNP) | VAF 52/416 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV58646406; called by muse, mutect2, varscan2
- ANKLE2 | c.1960C>T p.R654W | Missense Mutation (SNP) | VAF 73/373 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs371242395; called by muse, mutect2, varscan2
- BBS7 | c.1721C>G p.S574C | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.397); catalogued as rs765782762, COSV99145046; called by mutect2, varscan2
- BIRC3 | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 89/508 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); catalogued as rs1416464681; called by muse, mutect2, varscan2
- BRD3 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 59/794 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.565); catalogued as rs1464507474, COSV57705687; called by muse, mutect2
- CACNA1A | c.5506G>C p.E1836Q | Missense Mutation (SNP) | VAF 73/438 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100803027; called by muse, mutect2, varscan2
- CAND1 | c.486G>C p.L162F | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as COSV73338526; called by mutect2, varscan2
- CCDC198 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 45/310 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.884); catalogued as rs765567833; called by muse, mutect2, varscan2
- CCDC73 | c.1006C>T p.L336F | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465612206; called by muse, mutect2, varscan2
- CD3E | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 62/345 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62346318; called by muse, mutect2, varscan2
- CDHR1 | c.1544G>C p.G515A | Missense Mutation (SNP) | VAF 54/331 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV60566911; called by muse, mutect2, varscan2
- CDK5R2 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 116/695 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as rs868760743; called by muse, mutect2, varscan2
- CPD | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 95/692 reads (14%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV56710587; called by muse, mutect2, varscan2
- CWC22 | c.1805G>C p.R602T | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748110900, COSV55431000; called by mutect2, varscan2
- DDX4 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 46/290 reads (16%) | catalogued as COSV100737779; called by mutect2, varscan2
- DFFA | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 71/408 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs750382901, COSV65477439; called by muse, mutect2, varscan2
- DHX38 | c.3182C>T p.S1061L | Missense Mutation (SNP) | VAF 79/463 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs774324893; called by muse, mutect2, varscan2
- DST | c.1724C>T p.S575L (on ENST00000361203 / NM_001374722.1; = p.S249L on NM_001723.6) | Missense Mutation (SNP) | VAF 46/371 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV99752257; called by muse, mutect2, varscan2
- DYNC2H1 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as rs1212515834, COSV62093212; called by mutect2, varscan2
- EFCAB6 | c.4114G>A p.D1372N | Missense Mutation (SNP) | VAF 69/382 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs113498685, COSV99413493; called by muse, varscan2
- F13B | c.1754C>G p.S585C | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs147163101; called by mutect2, varscan2
- FAM13A | c.2782G>A p.D928N | Missense Mutation (SNP) | VAF 61/416 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as rs145220213; called by muse, mutect2, varscan2
- GJC3 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 103/566 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1471149051, COSV57209826; called by muse, mutect2, varscan2
- GPR182 | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 93/650 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs777562568; called by muse, mutect2, varscan2
- HENMT1 | c.1080G>C p.E360D | Missense Mutation (SNP) | VAF 39/532 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100898668; called by muse, mutect2
- HNF4G | c.1101G>C p.Q367H (on ENST00000354370 / NM_001330561.2; = p.Q414H on NM_004133.5) | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV62968009; called by muse, mutect2, varscan2
- HOATZ | c.400-1G>C p.X134_splice (on ENST00000375618 / NM_001100388.1; = p.X161_splice on NM_207430.2) | Splice Site (SNP) | VAF 37/266 reads (14%) | catalogued as COSV60442255; called by muse, mutect2, varscan2
- HSD11B1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 83/409 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV54826130; called by muse, mutect2, varscan2
- IDE | c.542G>A p.R181K | Missense Mutation (SNP) | VAF 62/351 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.861); catalogued as rs1346925336, COSV56425540; called by muse, mutect2, varscan2
- IL5 | c.404G>C p.*135Sext*2 | Nonstop Mutation (SNP) | VAF 39/217 reads (18%) | catalogued as COSV99185051, COSV99185055; called by muse, mutect2, varscan2
- IQCC | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 20/603 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV52208156; called by muse, mutect2
- KIF1B | c.4642C>G p.Q1548E (on ENST00000377086 / NM_001365952.1; = p.Q1502E on NM_015074.3) | Missense Mutation (SNP) | VAF 73/471 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.078); catalogued as rs1331941619, COSV99823180; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KNTC1 | c.5504C>G p.S1835* | Nonsense Mutation (SNP) | VAF 47/305 reads (15%) | catalogued as rs751966081; called by muse, mutect2, varscan2
- KRAS | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 66/412 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55561078, COSV55580549, COSV55715402; called by muse, varscan2
- MAFB | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 144/795 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100965080; called by muse, mutect2, varscan2
- MMP8 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs763986009; called by mutect2, varscan2
- MUC16 | c.25603G>A p.E8535K | Missense Mutation (SNP) | VAF 129/336 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.763); catalogued as COSV101198984; called by muse, mutect2, varscan2
- NLRP9 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 50/615 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV60460162, COSV60463028; called by muse, mutect2
- NRXN1 | c.1193C>T p.T398M | Missense Mutation (SNP) | VAF 142/398 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147400611; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 140/387 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, varscan2
- OBSCN | c.11860G>A p.E3954K | Missense Mutation (SNP) | VAF 87/467 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.833); catalogued as COSV52735595; called by muse, mutect2, varscan2
- OR4E2 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 95/460 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV57731649; called by muse, mutect2, varscan2
- PCLO | c.3481G>C p.E1161Q | Missense Mutation (SNP) | VAF 64/424 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as COSV61635353; called by muse, mutect2, varscan2
- PDE3B | c.2947C>G p.Q983E | Missense Mutation (SNP) | VAF 75/495 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56380030; called by muse, mutect2, varscan2
- PKD1 | c.5824C>T p.R1942C | Missense Mutation (SNP) | VAF 125/554 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs780100275, CM1513823; called by muse, mutect2, varscan2
- PNPLA3 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 77/515 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.389); catalogued as COSV53378438; called by muse, mutect2, varscan2
- PRICKLE4 | c.77G>C p.G26A (on ENST00000359201; = p.G66A on NM_013397.6) | Missense Mutation (SNP) | VAF 69/494 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.386); catalogued as rs766459458; called by muse, mutect2, varscan2
- PRKRIP1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 54/410 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs1312585278; called by muse, mutect2, varscan2
- RCAN1 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 154/762 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV58249993, COSV58250681; called by muse, mutect2, varscan2
- RNF169 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 69/365 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as rs772075431; called by muse, mutect2, varscan2
- SAAL1 | c.682C>G p.Q228E | Missense Mutation (SNP) | VAF 83/508 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1364410937, COSV55514538; called by muse, mutect2, varscan2
- SEZ6 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 81/573 reads (14%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.091); catalogued as rs1370807312; called by muse, mutect2, varscan2
- SLC7A3 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 171/395 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as rs868644826, COSV53227672; called by muse, mutect2, varscan2
- SNX17 | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52009322; called by muse, mutect2
- SPAG17 | c.1956G>A p.M652I | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV60456688; called by muse, mutect2, varscan2
- SPTA1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as COSV63758029; called by mutect2, varscan2
- TCF25 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 29/256 reads (11%) | catalogued as rs377036991; called by muse, mutect2, varscan2
- THPO | c.1268C>T p.S423F (on ENST00000649095 / NM_001290003.1; = p.S283F on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/509 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.017); catalogued as rs768017646, COSV52616185, COSV52616323; called by muse, mutect2
- TONSL | c.1095G>A p.M365I | Missense Mutation (SNP) | VAF 65/478 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.388); catalogued as rs201856507; called by muse, mutect2, varscan2
- TTC17 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 112/547 reads (20%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as rs910654091; called by muse, mutect2, varscan2
- TTN | c.98362G>A p.E32788K (on ENST00000591111; = p.E25364K on NM_003319.4) | Missense Mutation (SNP) | VAF 49/283 reads (17%) | PolyPhen benign (0.397); catalogued as rs867840992; called by muse, mutect2, varscan2
- TTN | c.69769G>A p.E23257K (on ENST00000591111; = p.E15833K on NM_003319.4) | Missense Mutation (SNP) | VAF 53/369 reads (14%) | PolyPhen benign (0.015); catalogued as rs751312481; called by muse, mutect2, varscan2
- UCHL1 | c.113C>G p.S38C | Missense Mutation (SNP) | VAF 84/482 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.415); catalogued as rs891423143; called by muse, mutect2, varscan2
- ZNF221 | c.1518C>G p.F506L | Missense Mutation (SNP) | VAF 81/472 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs1384346404; called by muse, mutect2, varscan2
- ZNF311 | c.27G>C p.E9D | Missense Mutation (SNP) | VAF 43/538 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.108); catalogued as rs1284798216; called by muse, mutect2
- ZNF648 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 114/572 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.362); catalogued as rs546993253, COSV60572506; called by muse, mutect2, varscan2
- ZNF697 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 199/482 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs964117668; called by muse, mutect2, varscan2
- ABCA7 | c.1129C>G p.L377V | Missense Mutation (SNP) | VAF 76/558 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- ABCA7 | c.1330G>C p.E444Q | Missense Mutation (SNP) | VAF 91/488 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ACAD11 | c.1558G>C p.E520Q | Missense Mutation (SNP) | VAF 47/312 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ACSBG1 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); called by mutect2, varscan2
- ADAMTS4 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 110/625 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- AHNAK | c.6892C>G p.P2298A | Missense Mutation (SNP) | VAF 86/452 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.356); called by mutect2, varscan2
- ALMS1 | c.1715C>G p.S572C | Missense Mutation (SNP) | VAF 77/499 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ALMS1 | c.1997C>G p.S666C | Missense Mutation (SNP) | VAF 74/434 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ALMS1 | c.11098C>G p.H3700D | Missense Mutation (SNP) | VAF 42/298 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by mutect2, varscan2
- AMOTL1 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 98/534 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- AMY2A | c.1111G>C p.D371H | Missense Mutation (SNP) | VAF 47/314 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by mutect2, varscan2
- ANAPC10 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 48/325 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- ANKRD27 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 74/396 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ATP13A4 | c.2970C>G p.F990L | Missense Mutation (SNP) | VAF 64/375 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.224); called by muse, varscan2
- BIRC6 | c.6760G>C p.E2254Q | Missense Mutation (SNP) | VAF 39/287 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRD8 | c.2992G>A p.E998K | Missense Mutation (SNP) | VAF 65/451 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CADPS | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); called by mutect2, varscan2
- CC2D2A | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.208); called by muse, varscan2
- CCDC74A | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 60/483 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CCNA1 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 47/289 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- CDHR2 | c.2967C>G p.I989M | Missense Mutation (SNP) | VAF 65/396 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- CEPT1 | c.1147G>C p.D383H | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CHD3 | c.4345G>C p.E1449Q | Missense Mutation (SNP) | VAF 74/340 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CHD9 | c.4641G>C p.E1547D | Missense Mutation (SNP) | VAF 74/399 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL6A5 | c.5642C>A p.S1881Y (on ENST00000312481; = p.S1877Y on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/471 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- COLEC12 | c.1305C>G p.I435M | Missense Mutation (SNP) | VAF 56/298 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CTH | c.363C>G p.F121L | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.034); called by mutect2, varscan2
- CTXN3 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 48/269 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- DBN1 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 103/552 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- DCHS1 | c.5230G>A p.E1744K | Missense Mutation (SNP) | VAF 70/460 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- DENND2D | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 36/292 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- DEPDC1B | c.575C>G p.S192* | Nonsense Mutation (SNP) | VAF 29/167 reads (17%) | called by muse, mutect2, varscan2
- DERA | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 66/414 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DUSP21 | c.10T>C p.S4P | Missense Mutation (SNP) | VAF 41/225 reads (18%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUXB | c.477G>C p.K159N | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- EBAG9 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 53/374 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.157); called by mutect2, varscan2
- EHMT1 | c.1701C>G p.N567K | Missense Mutation (SNP) | VAF 105/525 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ELF1 | c.594G>C p.K198N | Missense Mutation (SNP) | VAF 54/322 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ETAA1 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 76/454 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2
- EXD2 | c.1799C>G p.S600* (on ENST00000312994 / NM_001193362.1; = p.S475* on NM_018199.3) | Nonsense Mutation (SNP) | VAF 79/442 reads (18%) | called by muse, mutect2, varscan2
- FAM47A | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 55/596 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.12); called by muse, mutect2
- FBXL17 | c.2065C>G p.Q689E | Missense Mutation (SNP) | VAF 58/336 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- FOXD1 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 95/632 reads (15%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- FREM3 | c.1917G>C p.E639D | Missense Mutation (SNP) | VAF 100/565 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- FYB1 | c.65G>C p.R22T | Missense Mutation (SNP) | VAF 81/477 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- GBF1 | c.5065G>C p.D1689H (on ENST00000369983 / NM_001377137.1; = p.D1688H on NM_004193.3) | Missense Mutation (SNP) | VAF 17/575 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- GOLGA6L7 | c.297G>C p.Q99H | Missense Mutation (SNP) | VAF 59/312 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GPR37L1 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 115/602 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- GRIN1 | c.2267C>G p.S756W | Missense Mutation (SNP) | VAF 96/557 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GSDME | c.702C>A p.F234L | Missense Mutation (SNP) | VAF 33/260 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- H3C3 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 59/508 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.457); called by muse, mutect2
- HMG20A | c.944C>G p.S315* | Nonsense Mutation (SNP) | VAF 34/416 reads (8%) | called by muse, mutect2
- IFNA16 | c.479G>A p.S160N | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.203); called by mutect2, varscan2
- IGSF10 | c.6803C>T p.S2268F | Missense Mutation (SNP) | VAF 13/412 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2
- IL12A | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 66/402 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IL5 | c.21G>C p.L7F | Missense Mutation (SNP) | VAF 77/370 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IPO9 | c.1123-1G>C p.X375_splice | Splice Site (SNP) | VAF 33/203 reads (16%) | called by muse, mutect2, varscan2
- ITGA8 | c.1390G>C p.D464H | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- JAKMIP2 | c.157C>G p.Q53E | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by mutect2, varscan2
- KAZALD1 | c.294C>G p.F98L | Missense Mutation (SNP) | VAF 40/758 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2
- KIAA2012 | c.3346G>C p.E1116Q | Missense Mutation (SNP) | VAF 97/474 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KIF12 | c.1396G>C p.E466Q (on ENST00000640217; = p.E328Q on NM_138424.1) | Missense Mutation (SNP) | VAF 56/298 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- KNTC1 | c.5369C>G p.S1790C | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LDHD | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 97/581 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- ME2 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 49/288 reads (17%) | called by muse, mutect2, varscan2
- MIER1 | c.1071-1G>C p.X357_splice (on ENST00000355356 / NM_001077701.3; = p.X374_splice on NM_020948.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 45/254 reads (18%) | called by muse, mutect2, varscan2
- MMRN1 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 16/474 reads (3%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); called by muse, mutect2
- MTCL1 | c.1202_1211delinsGAGGGC p.E401Gfs*4 (on ENST00000306329 / NM_001378206.1; = p.E41Gfs*4 on NM_015210.4) | Frame Shift Del (DEL) | VAF 152/542 reads (28%) | called by pindel, varscan2*
- NDUFS3 | c.480C>G p.F160L | Missense Mutation (SNP) | VAF 61/284 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- NECTIN3 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 64/346 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- NKX2-6 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 70/530 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NPR1 | c.543A>C p.Q181H | Missense Mutation (SNP) | VAF 194/568 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OAS3 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 80/485 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- OR14K1 | c.506C>G p.S169C | Missense Mutation (SNP) | VAF 65/342 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PDE5A | c.2036C>G p.S679* | Nonsense Mutation (SNP) | VAF 65/327 reads (20%) | called by muse, mutect2, varscan2
- PER3 | c.3460G>T p.E1154* | Nonsense Mutation (SNP) | VAF 78/439 reads (18%) | called by muse, mutect2, varscan2
- PHKB | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 44/312 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PLA2G4D | c.181A>G p.T61A | Missense Mutation (SNP) | VAF 67/258 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PNISR | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 50/274 reads (18%) | called by muse, mutect2, varscan2
- PPM1J | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 89/484 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKN | c.1352G>A p.C451Y | Missense Mutation (SNP) | VAF 91/554 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PTPRU | c.4071C>G p.F1357L | Missense Mutation (SNP) | VAF 79/435 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- QSER1 | c.184C>T p.Q62* (on ENST00000399302; = p.Q191* on NM_001076786.3) | Nonsense Mutation (SNP) | VAF 44/459 reads (10%) | called by muse, mutect2
- RBM12B | c.1172C>G p.S391C | Missense Mutation (SNP) | VAF 49/389 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); called by mutect2, varscan2
- RPAP1 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 71/227 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2
- RPGRIP1 | c.3694C>G p.Q1232E | Missense Mutation (SNP) | VAF 58/344 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPTOR | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 77/455 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- SAMD8 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 89/569 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCG2 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 68/421 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEC24B | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- SESN3 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- SGF29 | c.384G>A p.M128I | Missense Mutation (SNP) | VAF 25/717 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2
- SLC37A3 | c.327G>C p.L109F | Missense Mutation (SNP) | VAF 49/413 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SPAG17 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); called by mutect2, varscan2
- SRSF6 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- ST7L | c.679C>G p.Q227E | Missense Mutation (SNP) | VAF 44/272 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- ST7L | c.678T>G p.Y226* | Nonsense Mutation (SNP) | VAF 48/276 reads (17%) | called by mutect2, varscan2
- SULF1 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 71/442 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- SUSD6 | c.491C>G p.S164C | Missense Mutation (SNP) | VAF 54/328 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- TDRKH | c.512C>G p.S171* | Nonsense Mutation (SNP) | VAF 59/385 reads (15%) | called by muse, mutect2, varscan2
- TEX14 | c.3337G>C p.E1113Q (on ENST00000240361 / NM_001201457.2; = p.E1067Q on NM_031272.5) | Missense Mutation (SNP) | VAF 54/301 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- TFF2 | c.62C>A p.A21E | Missense Mutation (SNP) | VAF 64/439 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- THAP9 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- TLL2 | c.1668G>A p.M556I | Missense Mutation (SNP) | VAF 81/451 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMEM219 | c.518G>C p.R173T | Missense Mutation (SNP) | VAF 61/380 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TNIK | c.2946C>G p.Y982* | Nonsense Mutation (SNP) | VAF 44/235 reads (19%) | called by muse, varscan2
- TOM1L1 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPRN | c.275_276insAGGG p.R93Gfs*138 | Frame Shift Ins (INS) | VAF 112/777 reads (14%) | called by mutect2, pindel, varscan2
- TTC17 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 91/471 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TUSC1 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 88/486 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.056); called by muse, varscan2
- UVRAG | c.70C>G p.P24A | Missense Mutation (SNP) | VAF 92/551 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- VLDLR | c.2611G>C p.D871H | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- VPS13A | c.2506G>C p.E836Q | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZIM3 | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 93/442 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF148 | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 76/485 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF408 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 74/609 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF620 | c.788C>G p.S263* | Nonsense Mutation (SNP) | VAF 90/473 reads (19%) | called by muse, mutect2, varscan2
- ZNF716 | c.1108C>T p.H370Y | Missense Mutation (SNP) | VAF 54/427 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF729 | c.849_851delinsAA p.R284Kfs*29 | Frame Shift Del (DEL) | VAF 42/392 reads (11%) | called by pindel, varscan2*
- ZNF749 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 107/538 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- ZNF879 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 81/454 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- AARS2 | c.2229G>A p.Q743= | Silent (SNP) | VAF 31/384 reads (8%) | catalogued as rs955887304; called by muse, mutect2
- ADAMTS3 | c.2616C>T p.C872= | Silent (SNP) | VAF 41/265 reads (15%) | called by muse, mutect2, varscan2
- AMBRA1 | c.1335G>A p.V445= (on ENST00000458649 / NM_001367468.1; = p.V355= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 89/518 reads (17%) | called by muse, mutect2, varscan2
- ATP13A5 | c.1188C>T p.S396= | Silent (SNP) | VAF 65/487 reads (13%) | catalogued as rs779145810, COSV60867433; called by muse, mutect2, varscan2
- C14orf180 | c.198G>C p.S66= | Silent (SNP) | VAF 52/558 reads (9%) | catalogued as rs748580951, COSV59557867; called by muse, mutect2
- CAPN6 | c.915G>C p.L305= | Silent (SNP) | VAF 75/313 reads (24%) | called by muse, mutect2, varscan2
- CASQ2 | c.381C>T p.G127= | Silent (SNP) | VAF 130/357 reads (36%) | catalogued as rs775663612, CS117810; called by muse, mutect2, varscan2
- CCDC71L | c.657G>C p.V219= | Silent (SNP) | VAF 115/634 reads (18%) | called by muse, mutect2, varscan2
- CENPJ | c.2364G>A p.L788= | Silent (SNP) | VAF 43/459 reads (9%) | catalogued as rs763994591; called by muse, mutect2
- CERT1 | c.1419G>A p.V473= (on ENST00000405807 / NM_001130105.1; = p.V345= on NM_005713.3) | Silent (SNP) | VAF 48/285 reads (17%) | called by muse, mutect2, varscan2
- CHD3 | c.4167G>C p.R1389= | Silent (SNP) | VAF 44/309 reads (14%) | catalogued as COSV57877415, COSV57878121; called by muse, mutect2, varscan2
- CLTCL1 | c.4540C>T p.L1514= | Silent (SNP) | VAF 78/459 reads (17%) | catalogued as rs547779543, COSV54227691, COSV99595839; called by muse, mutect2, varscan2
- CNTNAP3 | c.3573C>T p.V1191= | Silent (SNP) | VAF 50/1310 reads (4%) | called by muse, mutect2
- COL14A1 | c.4980G>A p.G1660= | Silent (SNP) | VAF 62/364 reads (17%) | catalogued as COSV52850985, COSV52856009, COSV52862137; called by muse, mutect2, varscan2
- CROCC2 | c.3261C>T p.F1087= | Silent (SNP) | VAF 84/457 reads (18%) | called by muse, mutect2, varscan2
- DAOA | c.376C>T p.L126= | Silent (SNP) | VAF 68/382 reads (18%) | called by muse, mutect2, varscan2
- DIPK1B | c.345C>T p.I115= | Silent (SNP) | VAF 69/457 reads (15%) | called by muse, mutect2, varscan2
- DNAH10 | c.10134G>A p.L3378= (on ENST00000409039; = p.L3317= on NM_207437.3) | Silent (SNP) | VAF 110/587 reads (19%) | catalogued as rs1187971611, COSV68992153; called by muse, mutect2, varscan2
- DNAH12 | c.819G>A p.K273= | Silent (SNP) | VAF 67/347 reads (19%) | called by muse, mutect2, varscan2
- DPY19L3 | c.543C>G p.L181= | Silent (SNP) | VAF 79/408 reads (19%) | called by muse, mutect2, varscan2
- DST | c.20967G>A p.K6989= (on ENST00000361203 / NM_001374722.1; = p.K4686= on NM_015548.5) | Silent (SNP) | VAF 44/252 reads (17%) | catalogued as rs770025191; called by mutect2, varscan2
- EFCAB6 | c.4230G>A p.K1410= | Silent (SNP) | VAF 45/252 reads (18%) | called by muse, mutect2, varscan2
- EVPL | c.4506G>T p.L1502= | Silent (SNP) | VAF 77/495 reads (16%) | called by muse, mutect2, varscan2
- FAM78B | c.162C>T p.R54= | Silent (SNP) | VAF 80/541 reads (15%) | catalogued as COSV57976738; called by muse, mutect2, varscan2
- GABRG2 | c.922C>T p.L308= (on ENST00000361925 / NM_001375343.1; = p.L268= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/340 reads (6%) | called by muse, mutect2
- GOLGA4 | c.2763G>A p.K921= | Silent (SNP) | VAF 71/338 reads (21%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.882G>A p.K294= | Silent (SNP) | VAF 78/539 reads (14%) | called by muse, mutect2, varscan2
- GOLGA8K | c.102G>A p.R34= | Silent (SNP) | VAF 24/249 reads (10%) | called by muse, mutect2, varscan2
- HIVEP2 | c.1272C>T p.I424= | Silent (SNP) | VAF 72/466 reads (15%) | called by muse, mutect2, varscan2
- JUND | c.318C>A p.L106= | Silent (SNP) | VAF 128/760 reads (17%) | called by muse, mutect2, varscan2
- KALRN | c.5835C>G p.V1945= (on ENST00000360013 / NM_001024660.4; = p.V248= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/322 reads (17%) | called by muse, mutect2, varscan2
- KIF1B | c.4464C>G p.L1488= (on ENST00000377086 / NM_001365952.1; = p.L1442= on NM_015074.3) | Silent (SNP) | VAF 69/390 reads (18%) | called by muse, mutect2, varscan2
- KNDC1 | c.297C>G p.L99= | Silent (SNP) | VAF 26/364 reads (7%) | called by muse, mutect2
- LRP2 | c.3039C>T p.C1013= | Silent (SNP) | VAF 97/499 reads (19%) | catalogued as rs200245838, COSV99786679; called by muse, mutect2, varscan2
- LYPLA1 | c.426C>G p.L142= | Silent (SNP) | VAF 66/355 reads (19%) | catalogued as COSV57604754; called by muse, mutect2, varscan2
- MAGEL2 | c.324G>A p.L108= | Silent (SNP) | VAF 36/617 reads (6%) | called by muse, mutect2
- MGA | c.3249G>A p.L1083= | Silent (SNP) | VAF 80/311 reads (26%) | catalogued as rs768794183, COSV54960543; called by muse, mutect2, varscan2
- MTUS2 | c.2679G>A p.L893= | Silent (SNP) | VAF 78/417 reads (19%) | catalogued as COSV54984722, COSV54990837; called by muse, mutect2, varscan2
- NELL1 | c.363G>A p.L121= | Silent (SNP) | VAF 71/355 reads (20%) | called by muse, mutect2, varscan2
- NPAP1 | c.2442G>A p.S814= | Silent (SNP) | VAF 196/498 reads (39%) | catalogued as rs760434738, COSV61505018; called by muse, mutect2, varscan2
- OLFML2B | c.1536G>C p.R512= | Silent (SNP) | VAF 60/448 reads (13%) | called by muse, mutect2, varscan2
- OMG | c.30C>G p.L10= | Silent (SNP) | VAF 42/282 reads (15%) | called by mutect2, varscan2
- OR10A2 | c.93C>T p.L31= | Silent (SNP) | VAF 30/560 reads (5%) | catalogued as rs755891856; called by muse, mutect2
- OR6V1 | c.642C>T p.I214= | Silent (SNP) | VAF 125/631 reads (20%) | called by muse, mutect2, varscan2
- OSTF1 | c.117C>T p.I39= | Silent (SNP) | VAF 26/182 reads (14%) | called by muse, mutect2, varscan2
- PDZD2 | c.2661C>T p.D887= | Silent (SNP) | VAF 46/522 reads (9%) | catalogued as rs756642743, COSV99227242; called by muse, mutect2
- PGAP1 | c.465C>G p.L155= | Silent (SNP) | VAF 33/190 reads (17%) | called by muse, mutect2, varscan2
- PLCE1 | c.1569C>T p.I523= | Silent (SNP) | VAF 28/430 reads (7%) | called by muse, mutect2
- PPP1CB | c.387C>T p.I129= | Silent (SNP) | VAF 46/257 reads (18%) | catalogued as COSV56092325; called by muse, mutect2, varscan2
- PRTG | c.1575G>A p.L525= | Silent (SNP) | VAF 69/322 reads (21%) | catalogued as rs530463504; called by muse, mutect2, varscan2
- PTPRB | c.5031G>T p.R1677= | Silent (SNP) | VAF 47/254 reads (19%) | called by muse, mutect2, varscan2
- RALGAPB | c.3888G>A p.L1296= | Silent (SNP) | VAF 43/383 reads (11%) | called by muse, mutect2, varscan2
- RBM25 | c.1611G>A p.K537= | Silent (SNP) | VAF 58/366 reads (16%) | called by muse, mutect2, varscan2
- RELN | c.849C>T p.I283= | Silent (SNP) | VAF 56/381 reads (15%) | called by muse, mutect2, varscan2
- RIN1 | c.717G>A p.E239= | Silent (SNP) | VAF 106/580 reads (18%) | called by muse, mutect2, varscan2
- RNF139 | c.594G>A p.L198= | Silent (SNP) | VAF 42/500 reads (8%) | called by muse, mutect2
- SLC25A42 | c.549G>A p.L183= | Silent (SNP) | VAF 81/453 reads (18%) | catalogued as rs780933553, COSV59381644; called by muse, mutect2, varscan2
- SLC2A1 | c.510C>T p.I170= | Silent (SNP) | VAF 33/298 reads (11%) | catalogued as rs748156710, COSV65287863; called by muse, mutect2, varscan2
- SLC52A3 | c.768C>T p.L256= | Silent (SNP) | VAF 73/417 reads (18%) | called by muse, mutect2, varscan2
- SLIT1 | c.2082G>T p.G694= | Silent (SNP) | VAF 103/572 reads (18%) | called by muse, mutect2, varscan2
- SSU72P5 | c.48C>T p.V16= | Silent (SNP) | VAF 41/463 reads (9%) | called by muse, varscan2
- STK40 | c.657C>T p.L219= | Silent (SNP) | VAF 48/321 reads (15%) | catalogued as rs374988648, COSV100828791; called by muse, mutect2, varscan2
- SUGCT | c.9G>A p.A3= | Silent (SNP) | VAF 69/463 reads (15%) | catalogued as rs1244252757; called by muse, mutect2, varscan2
- TBCD | c.3501G>A p.V1167= | Silent (SNP) | VAF 89/540 reads (16%) | called by muse, mutect2, varscan2
- TET1 | c.4557C>T p.I1519= | Silent (SNP) | VAF 104/614 reads (17%) | catalogued as rs752966129; called by muse, mutect2, varscan2
- TEX38 | c.549C>A p.L183= | Silent (SNP) | VAF 68/430 reads (16%) | called by muse, mutect2, varscan2
- TEX48 | c.21G>A p.L7= | Silent (SNP) | VAF 38/208 reads (18%) | catalogued as rs997141336; called by muse, mutect2, varscan2
- TNIP3 | c.207G>A p.L69= (on ENST00000509841 / NM_001244764.2; = p.L62= on NM_001128843.2) | Silent (SNP) | VAF 40/204 reads (20%) | called by mutect2, varscan2
- TRIM28 | c.747G>A p.V249= | Silent (SNP) | VAF 60/368 reads (16%) | called by muse, mutect2, varscan2
- TUBA8 | c.714C>T p.I238= | Silent (SNP) | VAF 85/444 reads (19%) | called by muse, mutect2, varscan2
- UBR3 | c.430C>T p.L144= | Silent (SNP) | VAF 57/830 reads (7%) | catalogued as rs778469181; called by muse, mutect2
- UNC79 | c.3912C>G p.A1304= (on ENST00000393151 / NM_001346218.2; = p.A1127= on NM_020818.5) | Silent (SNP) | VAF 19/683 reads (3%) | catalogued as COSV99829892; called by muse, mutect2
- XIRP2 | c.4185C>T p.I1395= (on ENST00000628543; = p.I1570= on NM_152381.6) | Silent (SNP) | VAF 70/412 reads (17%) | called by muse, mutect2, varscan2
- ZBTB41 | c.633C>T p.F211= | Silent (SNP) | VAF 57/309 reads (18%) | called by muse, mutect2, varscan2
- ZNF22 | c.294C>G p.L98= | Silent (SNP) | VAF 75/445 reads (17%) | called by muse, mutect2, varscan2
- ZNF304 | c.1536C>T p.F512= | Silent (SNP) | VAF 84/485 reads (17%) | catalogued as rs771294427; called by muse, mutect2, varscan2
- ZNF850 | c.2352C>G p.L784= | Silent (SNP) | VAF 84/539 reads (16%) | called by muse, mutect2, varscan2
- ABI3BP | c.1577-9243G>C | Intron (SNP) | VAF 26/184 reads (14%) | called by mutect2, varscan2
- ADAM10 | c.55+503C>T | Intron (SNP) | VAF 189/493 reads (38%) | catalogued as rs1300696349; called by muse, mutect2, varscan2
- ARMCX4 | c.1038+2479G>A | Intron (SNP) | VAF 140/566 reads (25%) | called by muse, mutect2, varscan2
- C2orf16 | chr2:27574274 C>G | 5'Flank (SNP) | VAF 52/294 reads (18%) | called by mutect2, varscan2
- C7orf77 | n.313C>T | RNA (SNP) | VAF 66/370 reads (18%) | called by mutect2, varscan2
- CTNNA2 | c.1057-79621C>T | Intron (SNP) | VAF 50/331 reads (15%) | called by muse, mutect2, varscan2
- DCHS2 | n.1755G>C | RNA (SNP) | VAF 73/412 reads (18%) | catalogued as COSV59723158; called by muse, mutect2, varscan2
- DCHS2 | n.1668G>T | RNA (SNP) | VAF 98/572 reads (17%) | called by muse, mutect2, varscan2
- G3BP1 | chr5:151770682 C>T | 5'Flank (SNP) | VAF 80/489 reads (16%) | catalogued as rs934349189; called by muse, mutect2, varscan2
- GRIK5 | c.2514+1214C>G | Intron (SNP) | VAF 57/295 reads (19%) | called by muse, mutect2, varscan2
- GRIK5 | c.2514+1021C>G | Intron (SNP) | VAF 100/613 reads (16%) | called by muse, mutect2, varscan2
- KBTBD4 | c.-30+253G>A | Intron (SNP) | VAF 67/409 reads (16%) | called by mutect2, varscan2
- MLIP | c.613-10957C>G | Intron (SNP) | VAF 91/455 reads (20%) | catalogued as COSV99231033; called by muse, mutect2, varscan2
- MYCBP2 | c.-19+119G>A | Intron (SNP) | VAF 125/647 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.34522+862C>G | Intron (SNP) | VAF 66/1030 reads (6%) | called by muse, mutect2
- TTN | c.10360+3850G>A | Intron (SNP) | VAF 40/236 reads (17%) | catalogued as rs762365120; called by mutect2, varscan2
- USP46 | c.*4701C>T | 3'UTR (SNP) | VAF 81/412 reads (20%) | called by muse, mutect2, varscan2
- ZFAND2A | chr7:1152324 G>C | 3'Flank (SNP) | VAF 55/312 reads (18%) | catalogued as rs1268713045; called by muse, mutect2, varscan2
